Somatic mutation profile of tumor specimen TARGET-10-PATWYL-09A (aliquot TARGET-10-PATWYL-09A-01D) from TARGET case TARGET-10-PATWYL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,586 days).
Specimen TARGET-10-PATWYL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0526c6e2-89ac-4fae-900a-843ac6ccbca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWYL-10A (Blood Derived Normal), aliquot TARGET-10-PATWYL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a8404cf-fbbd-44f8-bc18-4395feea9b5a

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Ins 2, Splice Site 1, 3'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC1 | c.1112T>G p.I371S | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61975748; called by muse, mutect2, varscan2
- DEPDC1B | c.315-1G>T p.X105_splice | Splice Site (SNP) | VAF 12/180 reads (7%) | catalogued as COSV99409918; called by muse, mutect2
- ERICH3 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs764527597, COSV58605360, COSV58606466; called by muse, mutect2
- KDM4E | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.084); catalogued as rs1210070611, COSV71678340; called by muse, mutect2, varscan2
- LETM1 | c.432dup p.A145Rfs*61 | Frame Shift Ins (INS) | VAF 20/68 reads (29%) | catalogued as rs745839823; called by mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- OR2L2 | c.404T>A p.I135K | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV63552155; called by muse, mutect2, varscan2
- RABEPK | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52335081; called by muse, mutect2, varscan2
- RAD51AP2 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs866611081; called by muse, mutect2
- SLC44A1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66025735; called by muse, mutect2, varscan2
- SNAI2 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50078935; called by muse, mutect2, varscan2
- STAB1 | c.6421C>T p.R2141C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs757372300, COSV58735450; called by muse, varscan2
- LEFTY2 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.111); called by muse, mutect2
- PDX1 | c.638C>A p.T213K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2
- TRRAP | c.3144C>A p.H1048Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.134); called by muse, mutect2
- URB1 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- USP7 | c.1463_1464insGGGCCCG p.C488Wfs*5 | Frame Shift Ins (INS) | VAF 31/97 reads (32%) | called by mutect2, pindel, varscan2
- CFAP65 | c.3582C>T p.S1194= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs202088592; called by muse, mutect2, varscan2
- GPRIN2 | c.996C>A p.A332= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs782751994; called by muse, mutect2
- MELK | c.1164C>A p.P388= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99974904; called by muse, mutect2
- MUC12 | c.10107G>T p.S3369= (on ENST00000379442; = p.S3226= on NM_001164462.1) | Silent (SNP) | VAF 27/230 reads (12%) | catalogued as rs780421979; called by muse, mutect2, varscan2
- NFATC1 | c.171G>A p.P57= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs138155687, COSV53707680; called by muse, mutect2, varscan2
- DOK3 | chr5:177503303 C>A | 3'Flank (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- PRDM11 | c.657-6859C>A | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1535C>T | RNA (SNP) | VAF 24/614 reads (4%) | called by muse, mutect2
